Somatic mutation profile of tumor specimen 0DKPWZ from CCDI case PBBYKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 4.7 years (1,730 days).
Specimen 0DKPWZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a6e9c36-1148-4879-9427-13873d90e16a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPWE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12545d81-9a58-45ce-a4e4-1604f7993503

The open-access MAF lists 71 somatic variants for this specimen: 37 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 22, 3'UTR 5, Intron 5, 5'UTR 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 385/680 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 92/1082 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as rs199599736; called by muse, mutect2
- AMOT | c.2639C>G p.P880R (on ENST00000371959 / NM_001113490.1; = p.P471R on NM_133265.3) | Missense Mutation (SNP) | VAF 108/533 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV59068941; called by muse, mutect2, varscan2
- CPNE6 | c.1537-8C>T | Splice Region (SNP) | VAF 29/219 reads (13%) | catalogued as rs1471348337; called by muse, mutect2, varscan2
- CUEDC1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 98/577 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776111825; called by muse, mutect2, varscan2
- FHL5 | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 58/1760 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100459374; called by muse, mutect2
- IFT172 | c.3130C>T p.R1044* | Nonsense Mutation (SNP) | VAF 96/1192 reads (8%) | catalogued as rs777676427; called by muse, mutect2
- MAGEB6B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 111/823 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs752201353, COSV69689719; called by muse, mutect2, varscan2
- MDN1 | c.4668G>T p.Q1556H | Missense Mutation (SNP) | VAF 343/2013 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs953875755; called by muse, mutect2, varscan2
- NLGN4Y | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.567); catalogued as COSV59294518; called by muse, mutect2
- NTN5 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 99/1300 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs767288192; called by muse, mutect2
- SPON2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 15/407 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV52056754; called by muse, mutect2
- TECPR1 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 130/852 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as rs574319111; called by muse, mutect2, varscan2
- VPS13B | c.8484G>T p.L2828F | Missense Mutation (SNP) | VAF 203/1968 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV62149598, COSV62161720; called by muse, mutect2, varscan2
- WWC2 | c.132-1G>C p.X44_splice | Splice Site (SNP) | VAF 120/594 reads (20%) | catalogued as COSV100968424; called by muse, mutect2, varscan2
- ADCY4 | c.1621T>A p.F541I | Missense Mutation (SNP) | VAF 82/1042 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2
- ADGRB3 | c.2701G>C p.A901P | Missense Mutation (SNP) | VAF 163/1313 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ARHGEF37 | c.625A>C p.N209H | Missense Mutation (SNP) | VAF 189/962 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ATCAY | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 73/672 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by mutect2, varscan2
- CFTR | c.4211T>C p.I1404T | Missense Mutation (SNP) | VAF 318/2298 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CRYBG1 | c.4691C>A p.T1564N | Missense Mutation (SNP) | VAF 165/1636 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2
- DHX35 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 67/2258 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- EXT2 | c.45C>G p.I15M (on ENST00000343631; = p.I48M on NM_000401.3) | Missense Mutation (SNP) | VAF 96/890 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- F2RL3 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); called by muse, mutect2
- HPGD | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 41/1427 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ITGA4 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 426/1464 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MYH2 | c.3527A>C p.E1176A | Missense Mutation (SNP) | VAF 164/1604 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPM2 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 72/834 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- NUMA1 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 109/980 reads (11%) | called by muse, mutect2, varscan2
- OR13D1 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 155/1118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDHB7 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 110/1222 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); called by muse, mutect2
- PRMT5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 43/1197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM19 | c.2042A>G p.E681G | Missense Mutation (SNP) | VAF 231/1284 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAMD4B | c.1793del p.G598Vfs*80 | Frame Shift Del (DEL) | VAF 66/664 reads (10%) | called by mutect2, pindel, varscan2
- SFRP2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 139/532 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, varscan2
- TRAPPC11 | c.2387G>C p.G796A | Missense Mutation (SNP) | VAF 307/1165 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TTN | c.50117T>A p.F16706Y (on ENST00000591111; = p.F9282Y on NM_003319.4) | Missense Mutation (SNP) | VAF 48/1888 reads (3%) | PolyPhen probably damaging (0.991); called by muse, mutect2
- ADCY10 | c.4689C>T p.T1563= | Silent (SNP) | VAF 88/1289 reads (7%) | catalogued as rs776149150; called by muse, mutect2
- BPIFC | c.519C>T p.S173= | Silent (SNP) | VAF 176/2008 reads (9%) | catalogued as rs752704609; called by muse, mutect2
- CHRNA7 | c.891C>T p.F297= | Silent (SNP) | VAF 60/483 reads (12%) | catalogued as rs1291409825, COSV60973790; called by muse, mutect2, varscan2
- DIDO1 | c.2535C>T p.R845= | Silent (SNP) | VAF 242/2657 reads (9%) | catalogued as rs140972357; called by muse, mutect2
- IL10RA | c.711C>T p.I237= | Silent (SNP) | VAF 88/717 reads (12%) | called by muse, mutect2, varscan2
- KCNH4 | c.1581C>T p.D527= | Silent (SNP) | VAF 77/651 reads (12%) | catalogued as rs1382569454, COSV52916145; called by muse, mutect2, varscan2
- MET | c.153C>G p.P51= | Silent (SNP) | VAF 144/1648 reads (9%) | catalogued as COSV100577310; called by muse, mutect2
- OR5V1 | c.846C>A p.T282= | Silent (SNP) | VAF 141/1148 reads (12%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1608C>T p.T536= | Silent (SNP) | VAF 36/299 reads (12%) | catalogued as rs1554124792, COSV63539543; called by muse, mutect2, varscan2
- PDE11A | c.750G>A p.K250= | Silent (SNP) | VAF 130/924 reads (14%) | called by muse, mutect2, varscan2
- PDE1C | c.585T>C p.R195= | Silent (SNP) | VAF 180/2624 reads (7%) | catalogued as COSV58525220; called by muse, mutect2
- POLK | c.624A>G p.L208= | Silent (SNP) | VAF 162/1924 reads (8%) | called by muse, mutect2
- PRAMEF15 | c.903C>A p.L301= | Silent (SNP) | VAF 104/1152 reads (9%) | called by muse, mutect2
- PRAMEF17 | c.1155C>T p.R385= | Silent (SNP) | VAF 75/1656 reads (5%) | catalogued as rs748804075, COSV65816666; called by muse, mutect2
- PTK7 | c.2226G>A p.E742= | Silent (SNP) | VAF 123/854 reads (14%) | called by muse, mutect2, varscan2
- RADIL | c.603G>C p.G201= | Silent (SNP) | VAF 56/780 reads (7%) | catalogued as COSV68201547; called by muse, mutect2
- SEC31A | c.1969T>C p.L657= (on ENST00000355196 / NM_001318120.1; = p.L618= on NM_016211.4) | Silent (SNP) | VAF 149/1106 reads (13%) | called by muse, mutect2, varscan2
- THOC2 | c.3675G>A p.E1225= | Silent (SNP) | VAF 139/873 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.1803T>G p.V601= | Silent (SNP) | VAF 319/1199 reads (27%) | called by muse, mutect2, varscan2
- WDFY3 | c.10392G>C p.S3464= | Silent (SNP) | VAF 62/1319 reads (5%) | called by muse, mutect2
- WDR62 | c.210C>T p.A70= | Silent (SNP) | VAF 90/962 reads (9%) | catalogued as COSV53077894; called by muse, mutect2
- WNT7B | c.999C>T p.F333= | Silent (SNP) | VAF 90/976 reads (9%) | catalogued as rs1340632593; called by muse, mutect2
- ARRB1 | c.414+42C>G | Intron (SNP) | VAF 55/517 reads (11%) | called by muse, mutect2, varscan2
- ASAH1 | c.*75G>T | 3'UTR (SNP) | VAF 240/911 reads (26%) | called by muse, mutect2, varscan2
- FAM161A | c.-89C>G | 5'UTR (SNP) | VAF 15/130 reads (12%) | catalogued as rs1316420702; called by muse, mutect2
- FCRLA | c.568+75G>T | Intron (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1859G>A | Intron (SNP) | VAF 79/576 reads (14%) | called by muse, mutect2, varscan2
- LCE1B | c.*47T>G | 3'UTR (SNP) | VAF 112/1214 reads (9%) | called by muse, mutect2
- MAD2L2 | c.-5G>A | 5'UTR (SNP) | VAF 93/802 reads (12%) | called by muse, mutect2, varscan2
- NDUFAF7 | c.623-58A>C | Intron (SNP) | VAF 71/388 reads (18%) | called by muse, mutect2, varscan2
- POLR3G | c.*81A>G | 3'UTR (SNP) | VAF 188/1730 reads (11%) | catalogued as rs1306626131; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12825A>C | Intron (SNP) | VAF 35/1315 reads (3%) | called by muse, mutect2
- SRRD | c.*2389A>T | 3'UTR (SNP) | VAF 32/287 reads (11%) | called by mutect2, varscan2
- ZNF800 | c.*37T>A | 3'UTR (SNP) | VAF 187/2364 reads (8%) | called by muse, mutect2
